Surgical pathology report (de-identified scan), TCGA case TCGA-12-1599, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1599-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

12-1599

Surg Path

CLINICAL HISTORY:

Right parietal brain tumor. Visual hallucinations and headaches.

Preoperative MRI: MRI for surgical localization purposes redemonstrating right temporal peripherally enhancing mass with several additional areas of enhancement adjacent to the dominant mass.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. Previously submitted as frozen section AF1 is a 2 x 2 x 0.3 cm aggregate of soft brown tissue and a blue tissue paper that is entirely submitted in block A1. Representative sections are submitted in a blue tissue paper in blocks A2-3 with a small portion of the tissue remaining in the container.

B. "Brain tissue", received fresh and placed in formalin is a 0.7 x 0.5 x 0.2 cm aggregate of soft tan-brown tissue which is placed in a blue mesh and submitted in block B1 a small portion of tissue remains in the container.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis. In some areas, many macrophages are seen, and there are increased numbers of granular mitoses. An LFB stain is non-contributory.

IMMUNOHISTOCHEMICAL FINDINGS:

An immunohistochemical stain for Ki-67 shows a proliferation index of approximately 5%-10%. GFAP highlights the tumor cells. Ham56 highlights the numerous macrophages. NFP show preserved axons within foci of increased numbers of macrophages.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV). SEE COMMENT.

B. "BRAIN TISSUE" (CRANIOTOMY):

HIGH-GRADE ASTROCYTOMA. SEE COMMENT.

COMMENT: In some areas there are prominent macrophage infiltrates associated with axonal preservation and granular mitoses. Histologically, these features raise the possibility of coexisting demyelinating disease. While the simultaneous detection of glioblastoma and multiple sclerosis is exceptionally rare [REDACTED] I would recommend clinical correlation to exclude the possibility.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[page 2 of 3]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

12-1599

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (48% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (44% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (83% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (86% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A2).

MGMT - POSITIVE (40% OF TUMOR CELLS)

EGFR wt - POSITIVE (2-3+ IN 90% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - NEGATIVE (2-3+ IN 70% OF TUMOR CELLS)

pS6 - POSITIVE (2+ IN 40% OF TUMOR CELLS)

pAKT - PENDING

COMMENT: pAKT testing will be performed and reported as an addendum.

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 3:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A2).

[REDACTED] for [REDACTED]

[page 3 of 3]
pAKT - POSITIVE (2+ IN 30% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] [REDACTED] [REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED] [REDACTED]

12-1599

Source: NCI Genomic Data Commons file ed732741-a51a-4471-92a3-f53f51170979 (TCGA-12-1599.E122C279-8BA9-4624-A00F-F530CC8F58AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).